TCGA case TCGA-DY-A1DE — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5555fbdd-962f-4d79-b36c-ae3c3cc4aff4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 56.1 years (20,504 days); Year of diagnosis: 2001; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,932 days (10.8 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 14; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium; Regimen or line of therapy: Mayo Clinic Regimen; Days to treatment start: 46 days; Days to treatment end: 78 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 174 days; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium; Regimen or line of therapy: Mayo Clinic Regimen; Days to treatment start: 291 days; Days to treatment end: 379 days (1.0 years); Treatment outcome: Complete Response.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 65.2 years (23,820 days); Days to diagnosis: 3,316 days (9.1 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (2 entries)
- Day 3,316 (post initial treatment): Progression or recurrence: Yes.
- Follow-up contacts recording only the day: day 3,667, day 3,932.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- KRAS mutation, nos: Positive; Mutation codon: 61.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 160 cm; BMI: 27.3.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DY-A1DE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 150 mg.
  Slide TCGA-DY-A1DE-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DY-A1DE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DY-A1DE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Microsatellite instability: No; Loci tested count: 5; Loci abnormal count: 0; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: Yes; History colon polyps: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Mayo 425-20.
- Follow-up form: New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,932 days; disease-specific survival: no event (censored), 3,932 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 3,316 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-DY-A1DE-01): tumor purity 0.75, ploidy 3.09, whole-genome doublings 1 (call status: legacy_call).
